Somatic mutation profile of tumor specimen 0DU3LJ from CCDI case PBCKJC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 19.1 years (6,973 days).
Specimen 0DU3LJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f84a245b-3f2a-41a3-843f-9a627bb3a1be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU3ML (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cc740f6-4e46-4ab4-ab8e-dad4461721b5

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC42BPG | c.1843G>T p.A615S | Missense Mutation (SNP) | VAF 124/1136 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV61348159; called by muse, mutect2, varscan2
- LBP | c.689A>G p.Y230C | Missense Mutation (SNP) | VAF 31/1417 reads (2%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99461457; called by muse, mutect2
- CAVIN2 | c.603C>G p.D201E | Missense Mutation (SNP) | VAF 62/2198 reads (3%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, mutect2
- OSTC | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 252/3388 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- TUBA8 | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 50/1552 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DNAH5 | c.10152T>G p.P3384= | Silent (SNP) | VAF 399/1301 reads (31%) | called by muse, mutect2, varscan2
- CLIC5 | c.884-57T>C | Intron (SNP) | VAF 45/541 reads (8%) | called by muse, mutect2
